Somatic mutation profile of tumor specimen TARGET-10-PAREPF-09A (aliquot TARGET-10-PAREPF-09A-01D) from TARGET case TARGET-10-PAREPF, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.5 years (2,018 days).
Specimen TARGET-10-PAREPF-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0d0ee993-9e7a-4fa0-8303-dab69020e58c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAREPF-10A (Blood Derived Normal), aliquot TARGET-10-PAREPF-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e69d51a-68bf-4447-82f4-62542a057f7a

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, Frame Shift Del 2, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BICRAL | c.487del p.L163Cfs*4 | Frame Shift Del (DEL) | VAF 60/136 reads (44%) | catalogued as COSV58407505; called by mutect2, pindel, varscan2
- BPIFB2 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs777102463, COSV50068467; called by muse, mutect2, varscan2
- CCDC149 | c.751C>T p.R251W | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199742117; called by muse, mutect2, varscan2
- EDEM2 | c.25C>T p.L9F | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs1473138678; called by muse, mutect2
- HNRNPA2B1 | c.61del p.R21Vfs*8 (on ENST00000354667 / NM_031243.3; = p.R9Vfs*8 on NM_002137.4) | Frame Shift Del (DEL) | VAF 27/67 reads (40%) | catalogued as COSV100522991, COSV61158682; called by mutect2, pindel, varscan2
- NECTIN3 | c.1588G>A p.E530K | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.771); catalogued as rs778205129, COSV60551532; called by muse, mutect2, varscan2
- EXPH5 | c.994C>G p.P332A | Missense Mutation (SNP) | VAF 54/111 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- SOCS4 | c.1283T>G p.V428G | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ITGA2B | c.2559G>C p.G853= | Silent (SNP) | VAF 21/68 reads (31%) | called by muse, mutect2, varscan2
- SLCO4C1 | c.1257C>T p.F419= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs763876375, COSV60517604; called by muse, mutect2, varscan2
- THSD7B | c.4056A>G p.G1352= (on ENST00000272643; = p.G1350= on NM_001316349.2) | Silent (SNP) | VAF 15/40 reads (38%) | called by muse, mutect2, varscan2
- POM121L4P | n.1258C>T | RNA (SNP) | VAF 9/13 reads (69%) | catalogued as rs1223876215; called by muse, mutect2, varscan2
- TEX14 | c.4457+135A>T | Intron (SNP) | VAF 7/10 reads (70%) | called by muse, varscan2
